Surgical pathology report (de-identified scan), TCGA case TCGA-JY-A93C, project TCGA-ESCA (Esophageal Carcinoma), tissue source site University Health Network, specimen TCGA-JY-A93C-01A (Primary Tumor).

[page 1 of 5]
Surgical Pathology Consultation Report

Patient Name:	[REDACTED]	Accession #:	[REDACTED]
MRN:	[REDACTED]	Collected:	
DOB:	[REDACTED]	Received:	
Gender:	M	Reported:	
Ordering MD:	[REDACTED]		
Copy To:			
Service:	[REDACTED]		
Visit #:	[REDACTED]		
Location:			
Facility:			

Specimen(s) Received

1. Lymph-Node: ST19 Splenic nodes
2. Lymph-Node: ST20 Celiac nodes
3. Lymph-Node: ST18 Common Hepatic nodes
4. Lymph node: INF pulm ligament ST9L
5. Esophagus: thoracic esophagus and proximal stomach esophageal margin QS
6. Lymph node: station 7
7. Lymph node: station 17
8. Lymph node: station 16
9. Lymph node: station 8
10. Esophagus: final oesophageal margin
11. Soft Tissue: final gastric margin
12. Soft Tissue: final #2 gastric and oesophageal ring margin

ICD-O-3
Adenocarcinoma NOS 8140/3
Site: Esophagus, distal third
C15.5
J 4/18/14

Diagnosis

1. Lymph-Node: ST19 Splenic nodes:
- lymph node x1: negative for carcinoma
- adipose tissue with no significant abnormality
2. Lymph-Node: ST20 Celiac nodes:
- lymph nodes x4: negative for carcinoma
3. Lymph-Node: ST18 Common Hepatic nodes:
- adipose tissue with no significant abnormality
4. Lymph node: INF pulm ligament ST9L:
- lymph node x1: negative for carcinoma
5. Esophagus (thoracic) and proximal stomach (esophageal margin QS), resection:
- adenocarcinoma of distal esophagus, moderately to poorly differentiated, with mucinous component, involving GEJ and extending into proximal stomach, invading adventitia – see synoptic data and comment
- resection margins: negative for carcinoma – see comment
- metastatic adenocarcinoma in 3/17 lymph nodes (total lymph node count includes specimens #1, #2, #4, and #6 to #9)
6. Lymph node: station 7:
- lymph nodes x3: negative for carcinoma – see comment
7. Lymph node: station 17:

[page 2 of 5]
- metastatic adenocarcinoma in 2/2 lymph nodes

8. Lymph node: station 16:

- lymph nodes x2: negative for carcinoma

9. Lymph node: station 8:

- metastatic adenocarcinoma in 1/4 lymph nodes

10. Esophagus: final oesophageal margin:

- negative for carcinoma

11. Stomach: final gastric margin:

- negative for carcinoma

12. Stomach and esophagus: final #2 gastric and esophageal ring margin:

- negative for carcinoma

Comment

5 and 6. The tumor involves distal esophagus and extends into the stomach for a distance of 2.0 cm. The tumor is focally ~ 0.5 mm from the esophageal adventitial margin and also involves perigastric fat. The proximal part of the tumor is polypoid and is in a background of intestinal metaplasia in residual glandular mucosa.

There is focal mucinous differentiation with small mucin pools and there is focal area of poorly differentiated tumor. The mucinous component represents approximately 20% of the tumor. There is metastatic adenocarcinoma in 3/17 lymph nodes identified. There is infiltration of perinodal adipose tissue in specimen #7, labeled lymph node station 17.

One lymph node in specimen #6, labeled lymph node station 7, shows small hyalinized nodules with anthracotic pigment and microscopic birefringent particles. There are no acid fast bacilli or fungi identified by the ZN and PAS stains.

Synoptic Data

Clinical History:	Not known:
Specimen:	Esophagus Proximal stomach
Procedure:	Esophagogastrectomy
Primary Tumor Site:	Distal esophagus (lower thoracic esophagus)
Additional Sites Involved by Tumor:	Esophagogastric junction (EGJ) Proximal stomach and esophagogastric junction
Relationship of Tumor to Esophagogastric Junction:	Tumor midpoint lies in the proximal stomach or cardia and tumor involves the esophagogastric junction Distance of tumor center from esophagogastric junction: 1.5 cm
Histologic Type:	Adenocarcinoma
Histologic Grade:	G3: Poorly differentiated
Tumor Size:	Greatest dimension: 3.8 cm Additional dimension: 1.9 cm Additional dimension: 0.6 cm
Microscopic Tumor Extension:	Tumor invades through the muscularis propria into the periesophageal soft tissue (adventitia)
Proximal Margin:	Uninvolved by invasive carcinoma Uninvolved by dysplasia
Distal Margin:	Uninvolved by invasive carcinoma Uninvolved by dysplasia
Circumferential (Adventitial) or Deep Margin:	Uninvolved by invasive carcinoma All Margin Status All margins uninvolved by invasive carcinoma Distance of invasive carcinoma from closest margin: 0.5 mm Closest margin: Circumferential
Treatment Effect:	No prior treatment

[page 3 of 5]
Surgical Pathology Consultation Report

Lymph-Vascular Invasion:	Present
Perineural Invasion:	Present
TNM Descriptors:	Not applicable: .
Primary Tumor (pT):	pT3: Tumor invades adventitia
Regional Lymph Nodes (pN):	pN2: 3 to 6 nodes involved
	Number of regional lymph nodes examined: 17
	Number of regional lymph nodes involved: 3
Distant Metastasis (pM):	Not applicable: .
Additional Pathologic Findings:	*Intestinal metaplasia (Barrett's esophagus)

*Pathologic Staging is based on AJCC/UICC TNM, 7th Edition

Electronically verified by:

Clinical History

esophageal ca

Gross Description

1. The specimen is labeled with the patient's name and as "ST 19 splenic nodes".

Number of yellow tissue pieces: 3

Measurements: 0.8 x 0.4 x 0.2 cm to 2 x 1.3 x 0.4 cm.

1A submitted in toto

2. The specimen is labeled with the patient's name and as "ST20 celiac nodes".

Number of yellow tissue pieces: 4

Measurements: 0.3 x 0.3 x 0.3 cm to 1 x 0.5 x 0.4 cm.

2A submitted in toto

3. The specimen is labeled with the patient's name and as "ST18 hepatic nodes".

One piece of yellow tissue measuring 1.4 x 0.5 x 0.3 cm.

3A submitted in toto

4. The specimen is labeled with the patient's name and as "inferior pulmonary ligament ST9L".

One piece of gray tissue measuring 0.3x0.3x0.2cm.

4A submitted in toto

5. STOMACH RESECTION FOR TUMOR

GROSS EXAMINATION

RESECTION SPECIMEN: proximal gastrectomy and distal esophagus

FIXATION: Fixed

DIMENSIONS:

[page 4 of 5]
Length along lesser curvature 4.5 cm
Circumference of distal gastric margin 12.8 cm
Length of tubular esophagus if present 5 -cm
circumference esophagus margin 5.0 cm

TUMOR:

LOCATION:

- distal esophagus, GEJ and proximal stomach
- lesser curvature
- proportion of tumor mass located in esophagus & stomach: 1.5 cm long in esophagus and 2.0 cm long in stomach

- **CONFIGURATION:** exophytic

- **DIMENSIONS:** Diameters 3.8 x 1.9 cm
Depth 0.6 cm

- **DESCRIPTIVE CHARACTERISTICS:** tan and solid

- **PERFORATION:** no

- DISTANCE FROM MARGINS:

- PROXIMAL 3.3 cm
- DISTAL 1 cm
- RADIAL 0.1 cm

ESTIMATED DEPTH OF INVASION: into adventitia

LESIONS IN NONCANCEROUS STOMACH: no

LYMPH NODES: perigastric lymph nodes along the greater and lesser curvatures: no

2 pieces of tumor, one piece of mucosa of esophagus and one piece of gastric mucosa stored frozen

Representative Sections:

5A-5B esophageal margin en face frozen sections resubmitted
5C-5D distal margin en face frozen sections resubmitted
5E-5G remaining gastric margin en face
5H-5N upper half of tumor in toto sequentially
5O-5T rest of tumor in toto sequentially
5U transverse section of esophagus above tumor

6. The specimen is labeled with the patient's name and as "station 7".

Number of fatty tissue pieces: 2

Number of nodes: 3

Measurements: 1 x 0.8 x 0.3 cm to 3 x 1.2 x 0.6 cm.

The nodes are submitted in toto.

6A 2 nodes

6B and 6C 1 node bisected

7. The specimen is labeled with the patient's name and as "station 17".

Number of fatty tissue pieces: 1

Measurements: 4.5 x 4.5 x 2.5 cm.

2 nodes identified measuring 0.1 x 0.1 x 0.1 and 1.6 x 0.8 x 0.9 cm.

The nodes are submitted in toto.

7A 1 node

7B 1 node bisected

[page 5 of 5]
Surgical Pathology Consultation Report

8. The specimen is labeled with the patient's name and as "station 16".

Number of fatty tissue pieces: 1

Measurements: 4 x 3 x 0.5 cm.

2 nodes identified ranging in size from 0.1 x 0.1 x 0.1 to 0.3 x 0.3 x 0.3 cm.

The nodes are submitted in toto.

8A 2 nodes

8B 1 possible node

9. The specimen is labeled with the patient's name and as "station 8".

Number of fatty on tissue pieces: 1

Measurements: 8 x 3 x 0.5 cm.

4 nodes identified ranging in size from 0.1 x 0.1 x 0.1 to 1 x 0.4 x 0.3 cm

The nodes are submitted in toto.

9A 2 nodes

9B 2 nodes

10. The specimen is labeled with the patient's name and as "final esophageal margin". It consists of a stapled line margin measuring 3 x 0.4 x 0.3 cm.

10A soft tissue shaving

11. The specimen is labeled with the patient's name and as "final gastric margin". It consists of a segment of staple line margin measuring 6 x 2 x 1.8 cm.

11A-11C the staple line removed and the margin submitted

12. The specimen is labeled with the patient's name and as "final number 2 gastric and esophageal ring margin". It consists of 2 margins measuring 2.7 x 1.2 x 0.3 cm and 3.8 x 1 x 0.7-cm. The specimen is submitted in toto.

12A the smaller tissue sectioned(gastric)

12B-12C the longer(esophageal)

Quick Section Diagnosis

5A, 5B. esophageal margin (en face): negative for carcinoma

5C, 5D. representative sections of distal margin (en face): negative for carcinoma

Time reported to surgeon:

Source: NCI Genomic Data Commons file a4fe8e15-dc3a-4608-95ba-0385aa4a0c1a (TCGA-JY-A93C.AFA6B3D5-E514-42B0-84AA-251724FDBFBC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).